Somatic mutation profile of tumor specimen TCGA-3B-A9I3-01A (aliquot TCGA-3B-A9I3-01A-11D-A38Z-09) from TCGA case TCGA-3B-A9I3, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 62.9 years (22,985 days).
Specimen TCGA-3B-A9I3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 473cf0ce-d06e-411b-a5ac-c0e252472aaa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3B-A9I3-10A (Blood Derived Normal), aliquot TCGA-3B-A9I3-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c873b28b-ce61-479c-9404-bb53ebf996f0

The open-access MAF lists 45 somatic variants for this specimen: 35 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 9, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC1 | c.2884G>A p.V962M | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.872); catalogued as rs371105838; called by muse, mutect2, varscan2
- ABCG1 | c.1450T>A p.F484I | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100493950; called by muse, mutect2, varscan2
- ACAP2 | c.1226C>A p.P409H | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100461773; called by muse, mutect2
- BMP8A | c.920A>T p.Y307F | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100090084; called by muse, varscan2
- CCDC127 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.961); catalogued as COSV99371417; called by muse, mutect2, varscan2
- CRISPLD1 | c.871C>G p.Q291E | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV100081758, COSV51545551; called by muse, mutect2
- CTSK | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV99648622; called by muse, mutect2, varscan2
- DNM3 | c.2200G>A p.A734T (on ENST00000355305 / NM_001350206.2; = p.A728T on NM_015569.5) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.649); catalogued as COSV62458121; called by muse, mutect2, varscan2
- DUSP11 | c.158A>G p.H53R | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99730925; called by muse, mutect2
- FREM2 | c.3610A>C p.M1204L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.205); catalogued as rs1265144492, COSV99747783; called by muse, mutect2, varscan2
- GJA8 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.354); catalogued as rs782056871, COSV53788320; ClinVar: uncertain significance; called by muse, mutect2
- JCAD | c.1084G>T p.V362L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV100948224; called by muse, mutect2, varscan2
- KANSL1L | c.2435A>G p.N812S | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as COSV99910328; called by muse, mutect2, varscan2
- KIF1B | c.4366G>A p.G1456S (on ENST00000377086 / NM_001365952.1; = p.G1410S on NM_015074.3) | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99822867; called by muse, mutect2, varscan2
- LHX8 | c.482G>A p.C161Y | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99633385; called by muse, mutect2
- LRP1B | c.4013A>G p.E1338G | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101254577; called by muse, mutect2, varscan2
- MOSPD2 | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100996730; called by muse, mutect2, varscan2
- NELFB | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100546843; called by muse, mutect2, varscan2
- NPVF | c.92T>G p.V31G | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV99760194; called by muse, mutect2, varscan2
- OR10C1 | c.662G>A p.R221H (on ENST00000622521; = p.R219H on NM_013941.3) | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs74711365, COSV65822383, COSV65822987; called by muse, mutect2
- OR5D13 | c.751A>G p.T251A | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as rs761201512, COSV100686800; called by muse, mutect2
- PCDHA7 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.846); catalogued as COSV65342015; called by muse, varscan2
- PKNOX2 | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.084); catalogued as COSV100020497; called by muse, mutect2, varscan2
- PPP1R16A | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99477509; called by muse, mutect2, varscan2
- RASA3 | c.1671C>G p.F557L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV61866290; called by muse, mutect2, varscan2
- RB1 | c.2663+1G>A p.X888_splice | Splice Site (SNP) | VAF 19/105 reads (18%) | catalogued as COSV99923197, COSV99923929; called by muse, mutect2, varscan2
- SHROOM3 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99933899; called by muse, mutect2, varscan2
- STAG3 | c.2840G>T p.G947V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.101); catalogued as COSV100425767; called by muse, mutect2
- TAB1 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs779843526, COSV53373334; called by muse, mutect2, varscan2
- TICAM1 | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376421303; called by muse, mutect2, varscan2
- TP53BP1 | c.1617T>A p.D539E | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.301); catalogued as COSV99780125; called by muse, mutect2, varscan2
- VANGL1 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV100048996; called by muse, mutect2, varscan2
- WDR45 | c.718C>A p.L240I (on ENST00000376372 / NM_001029896.2; = p.L241I on NM_007075.3) | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0.03); catalogued as COSV59876150; called by muse, mutect2
- ZNF407 | c.6684G>T p.E2228D | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV100225282; called by muse, mutect2, varscan2
- ANKRD17 | c.5646A>G p.P1882= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV58218713; called by muse, mutect2, varscan2
- CSMD1 | c.5655T>C p.T1885= (on ENST00000520002; = p.T1884= on NM_033225.6) | Silent (SNP) | VAF 20/135 reads (15%) | catalogued as COSV100145759; called by muse, mutect2, varscan2
- MATN4 | c.1602C>T p.R534= (on ENST00000372754; = p.R493= on NM_003833.4) | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs757493559, COSV100636945; called by muse, mutect2, varscan2
- MRPS5 | c.1248A>T p.G416= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV99720750; called by muse, mutect2, varscan2
- MYO5B | c.2043C>T p.C681= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as rs2969930; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPIP5K2 | c.934C>A p.R312= | Silent (SNP) | VAF 67/335 reads (20%) | catalogued as COSV100383590; called by muse, mutect2, varscan2
- S100A7 | c.285C>T p.P95= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100906708; called by muse, mutect2, varscan2
- TNXB | c.11250C>A p.T3750= (on ENST00000647633; = p.T3503= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as COSV100926097; called by muse, mutect2, varscan2
- ZC3H3 | c.120G>A p.Q40= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs1228457978, COSV99367618; called by muse, mutect2, varscan2
- C9orf78 | c.-1C>G | 5'UTR (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100204168; called by muse, mutect2, varscan2
